TCGA case TCGA-DX-A6BA — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4dc28966-d2c4-4661-b71f-d7f85e536cb6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Alive.

Diagnoses (6)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,455 days); Year of diagnosis: 2008; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 15; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 28.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 11.8; Tumor length measurement: 24; Tumor width measurement: 18.7.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 12; Tumor length measurement: 28; Tumor width measurement: 22.
2. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Abdomen, NOS. Age at diagnosis: 54.4 years (19,863 days); Days to diagnosis: 408 days (1.1 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 13.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 13.5.
3. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 56.0 years (20,465 days); Days to diagnosis: 1,010 days (2.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4.5; Tumor width measurement: 4.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4.5; Tumor width measurement: 4.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 56.0 years (20,465 days); Days to diagnosis: 1,010 days (2.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 0.8.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 57.1 years (20,869 days); Days to diagnosis: 1,414 days (3.9 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 57.3 years (20,947 days); Days to diagnosis: 1,492 days (4.1 years); Prior treatment: Yes.

Follow-up (8 entries)
- Day 408 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 408 days (1.1 years); Discontiguous lesion count: 2.
- Day 1,010 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,010 days (2.8 years).
- Day 1,010 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 1,010 days (2.8 years).
- Day 1,414 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,414 days (3.9 years).
- Day 1,492 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,492 days (4.1 years).
- Days to follow up: 1,669 days (4.6 years); Disease response: With Tumor.
- Days to follow up: 2,009 days (5.5 years); Disease response: With Tumor.
- Days to follow up: 2,515 days (6.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 28.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6BA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 770 mg.
  Slide TCGA-DX-A6BA-01A-01-TSA: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 3; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A6BA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A6BA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower abdominal/Pelvic - Pelvic.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1493; Pharmaceutical therapy drug name: Pazopanib; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Targeted Molecular therapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 705; Days from index date to pharmaceutical treatment ended: 867; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 2, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 3: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 525; Days from index date to pharmaceutical treatment ended: 567; Pharmaceutical therapy drug name: Everolimus; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 4: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 525; Days from index date to pharmaceutical treatment ended: 567; Pharmaceutical therapy drug name: R1507; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 446; Days from index date to pharmaceutical treatment ended: 507; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,515 days; disease-specific survival: no event (censored), 2,515 days; disease-free interval: event (new tumor event after initially disease-free), 408 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 408 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6BA-01A-11D-A306-01): tumor purity 0.85, ploidy 3.41, whole-genome doublings 1.
